Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7819, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7819-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Prostate and bilateral seminal vesicles, radical prostatectomy:
Infiltrating prostatic adenocarcinoma.

Tumor Characteristics:

1. Histologic type: Infiltrating prostatic adenocarcinoma.
2. Location: Bilateral, see comment.
3. Gleason score:
- a. Primary pattern: 4/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 8/10.
- d. Pattern 5 areas: Not appreciated.
4. Perineural space invasion: Present.
5. Lymphovascular space invasion: Not identified.
6. Seminal vesicle involvement: Not identified.
7. High grade PIN: Focally present.

Surgical Margin Status:

1. Inferior/apical margin: Negative.
2. Proximal/bladder margin: Negative.
3. Inked prostatic margin: Positive with additional areas of intracapsular invasion, see comment.

Lymph Node Status:

See below.

- B. Lymph nodes, right pelvic area, regional dissection:
Number of lymph nodes identified: Three (3).
Number of lymph nodes demonstrating metastatic malignancy: Zero (0/3).

TNM classification: pT2c,N0.

COMMENTS:

Carcinoma is fairly prevalent, with examples best seen in sections A6-11. Perineural invasion is best seen in sections 6, 7 and 11. Invasion into the capsule is best seen in sections 7, 9 and 11 with the inked surgical margin of the prostate transected by carcinoma in section 7, from the distal left posterior aspects.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Malignant neoplasm prostate.
Postoperative Diagnosis:
Symptoms/Radiologic Findings:

SPECIMENS:

- A. Prostate.
B. Right pelvic lymph nodes.

SPECIMEN DATA

GROSS DESCRIPTION:

A. Container A is received in formalin labeled _____ and prostate is a 40 gram, previously inked and sampled radical prostatectomy specimen received for research, 5.1 x 5.0 x 3.8 cm. The right side is inked blue and the left side black. The specimen is further sectioned to posterior to show a smooth pale yellow area of discoloration at the distal level measuring 1.5 x 1.1 x 1.1 cm. The lesion abuts the inked posterior margin. Additional abnormalities are not identified. The seminal vesicals together measure 4.5 x 2.5 x 0.6 cm. Each is grossly uninvolved by lesion.

[page 2 of 2]
PATIENT INFORMATION

SPECIMEN INFORMATION

Representative sections are submitted as follows: 1 and 2--apical margin; 3--vesical margin; 4--distal left lateral; 5--distal right lateral; 6--distal right posterior; 7--distal left posterior; 8--mid left lateral; 9--mid right lateral; 10--mid right posterior; 11--mid left posterior; 12--proximal left lateral; 13--proximal right lateral; 14--proximal right posterior; 15--proximal left posterior; 16--origin of seminal vesicals; 17--representative left and right seminal vesicals.

Two cassettes for research labeled [REDACTED]

B. Container B is received in formalin labeled [REDACTED] 1 right pelvic lymph nodes. It consists of a 3.5 x 1.5 x 0.6 cm. mass of nodular yellow adipose tissue. On palpation three lymph nodes are identified ranging from 0.3 to 0.2 x 0.2 cm. to 2.5 x 1.5 x 0.9 cm. The largest node is bisected. The nodes are entirely submitted as follows; 1--two whole nodes; 2--one node bisected.

Source: NCI Genomic Data Commons file 230e0eb1-e085-4143-900b-9cfad35469e0 (TCGA-HC-7819.AB62F75E-D1F0-47F7-8A78-4151AF81D409.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).